Gene-level copy-number profile of tumor specimen TCGA-UY-A8OB-01A from TCGA case TCGA-UY-A8OB, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 64.0 years (23,360 days).
Specimen TCGA-UY-A8OB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.e88e4df6-1509-40b6-b9e3-b12962617453.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UY-A8OB-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b8b1f036-a82a-43a9-b7e5-3d21799df24d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 1,305; copy number 2: 34,536; copy number 3: 16,051; copy number 4: 6,513; copy number 5: 854; copy number 6: 481; copy number 12: 44; copy number 15: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UY-A8OB-01A-12D-A42D-01): tumor purity 0.72, ploidy 2.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,303,744–48,976,867, 14 genes (within-gene range 0–1): RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1.
- chr13:48,987,915–49,046,794, 2 genes: RNU6-60P, RAD17P2.
- chr13:50,082,169–50,906,856, 1 gene (within-gene range 0–1): DLEU1.
- chr13:50,361,410–51,200,252, 9 genes (within-gene range 0–1): RPL34P26, AL158195.1, DLEU7, RNA5SP28, RNASEH2B-AS1, RNASEH2B, GUCY1B2, RNA5SP29, C13orf42.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,381 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:178,164,008–179,147,973, 10 genes, copy number 6 (within-gene range 4–6): AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2.
- chr5:58,198–45,895,970, 710 genes, copy number 5–6 (broad region; genes not listed).
- chr7:27,617,474–27,844,564, 3 genes, copy number 5: AC007130.1, TAX1BP1-AS1, TAX1BP1.
- chr7:27,873,785–27,876,546, 1 gene, copy number 5: AC004549.1.
- chr9:97,412,096–97,601,743, 3 genes, copy number 5 (within-gene range 3–5): TDRD7, TMOD1, AL162385.1.
- chr10:42,185,339–65,880,289, 360 genes, copy number 5–15 (broad region; genes not listed).
- chr10:66,079,243–66,118,326, 1 gene, copy number 15: AC022017.1.
- chr17:19,061,912–21,783,465, 155 genes, copy number 5–12 (broad region; genes not listed).
- chr19:56,774,547–58,605,223, 138 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,305. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
